Gene-level copy-number profile of tumor specimen C3L-00913-03 from CPTAC case C3L-00913, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 66.7 years (24,378 days).
Specimen C3L-00913-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f5112689-4c8b-4baf-9ba2-33e98f23b02d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00913-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/a93e118f-b35d-496d-8627-aa3a754589c8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,983; copy number 2: 48,994; copy number 3: 1,684; copy number 4: 4; copy number 5: 21; copy number 7: 120; copy number 8: 25; copy number 9: 79; copy number 16: 6; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 253 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:154,596,012–156,767,788, 21 genes, copy number 5 (within-gene range 2–5): MIR3141, MIR1303, Y_RNA, LARP1, RN7SL803P, AC008379.1, FAXDC2, Metazoa_SRP, MIR378H, CNOT8, GEMIN5, MRPL22, AC008410.1, KIF4B, AC010476.2, AC010476.1, AC010591.1, AC008725.1, RNA5SP199, SGCD, AC011351.1.
- chr11:42,183,292–50,422,316, 224 genes, copy number 7–9 (broad region; genes not listed).
- chr19:27,638,483–27,646,483, 2 genes, copy number 18: ERVK-28, AC112702.1.
- chr19:29,665,459–29,921,653, 6 genes, copy number 16: PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58.

Autosomal genes at a single copy (total copy number 1): 5,127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
